Somatic mutation profile of tumor specimen 92862537-5f30-47db-a3e2-cc9d0c (aliquot 92862537-5f30-47db-a3e2-cc9d0c_D6_1) from CPTAC case 05BR045, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.0 years (22,264 days).
Specimen 92862537-5f30-47db-a3e2-cc9d0c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0cfe5ee-7eb6-4dde-adf3-b0ea150fdfb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4e998bbe-c506-4778-b321-135dae (Blood Derived Normal), aliquot 4e998bbe-c506-4778-b321-135dae_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62d22c40-32c3-4b32-b997-d7e5689af3fb

The open-access MAF lists 77 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Intron 5, Nonsense Mutation 2, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 210/356 reads (59%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by mutect2, varscan2
- ADRA2C | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1170395344; called by muse, mutect2, varscan2
- ATN1 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 344/840 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1555144312, COSV63110253; called by muse, mutect2, varscan2
- BCL9L | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 137/359 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100600270; called by muse, mutect2, varscan2
- CLIC5 | c.574C>G p.P192A (on ENST00000185206 / NM_001370649.1; = p.P33A on NM_016929.5) | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51763892; called by muse, mutect2
- COL9A3 | c.1602C>G p.S534R | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs146578812, COSV58986823, COSV58987810; called by muse, mutect2, varscan2
- DOP1A | c.7171C>T p.R2391C | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1024056692, COSV52283380; called by muse, varscan2
- EVC2 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 207/320 reads (65%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.805); catalogued as rs767317898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM47A | c.1078T>A p.S360T | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV60498502; called by muse, mutect2, varscan2
- FMN2 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60437558; called by mutect2, varscan2
- GPATCH4 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV58039701; called by muse, mutect2, varscan2
- IQGAP2 | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs751786825, COSV57171656; called by muse, mutect2, varscan2
- ITIH6 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs780083076; called by muse, mutect2, varscan2
- LRRC70 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV100320363; called by muse, mutect2, varscan2
- MAP1LC3A | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs754072527; called by mutect2, varscan2
- OR6K2 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62743201; called by muse, mutect2
- RAI2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 136/463 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs140631545, COSV58963272; called by muse, varscan2
- RIMS1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53436901; called by muse, mutect2, varscan2
- SLC15A3 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57172844; called by muse, mutect2, varscan2
- STXBP5 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as COSV51655829; called by muse, mutect2, varscan2
- UBQLNL | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759729325, COSV66492944; called by muse, varscan2
- ADAM7 | c.1907_1908del p.Q636Lfs*3 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- AFDN | c.367dup p.E123Gfs*7 | Frame Shift Ins (INS) | VAF 25/52 reads (48%) | called by mutect2, pindel, varscan2
- AKT3 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANAPC2 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- BCAS4 | c.505A>T p.T169S | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); called by mutect2, varscan2
- C1orf159 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- CDK12 | c.357_358insGAACC p.R120Efs*6 | Frame Shift Ins (INS) | VAF 49/94 reads (52%) | called by mutect2, pindel, varscan2
- CTDNEP1 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX2 | c.1843T>C p.F615L | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK5 | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ENDOD1 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 117/347 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- GDF7 | c.1163C>A p.S388* | Nonsense Mutation (SNP) | VAF 192/614 reads (31%) | called by muse, mutect2, varscan2
- GTPBP4 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- LAMB1 | c.4817A>G p.Q1606R | Missense Mutation (SNP) | VAF 98/182 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- PAX1 | c.887_895del p.L296_I298del | In Frame Del (DEL) | VAF 118/266 reads (44%) | called by mutect2, pindel, varscan2
- PHC2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, varscan2
- PHC2 | c.493G>C p.A165P | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, varscan2
- PLEKHG6 | c.1122G>C p.E374D | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- POP1 | c.714G>C p.M238I | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PRRC2C | c.6806G>T p.G2269V (on ENST00000367742; = p.G2267V on NM_015172.4) | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.231); called by mutect2, varscan2
- PUS7 | c.1420A>G p.M474V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, varscan2
- RERGL | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RSBN1 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEC24A | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- SEMA6D | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- SLC2A1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 215/1154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by mutect2, varscan2
- SPEG | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TMEM151A | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- TTC24 | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBQLNL | c.513C>G p.C171W | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.066); called by muse, varscan2
- XAB2 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 55/452 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2
- AFMID | c.243C>A p.P81= | Silent (SNP) | VAF 61/265 reads (23%) | catalogued as rs746480044; called by muse, mutect2, varscan2
- APOB | c.10026C>T p.S3342= | Silent (SNP) | VAF 134/282 reads (48%) | called by muse, mutect2, varscan2
- CHST11 | c.354C>T p.L118= | Silent (SNP) | VAF 136/368 reads (37%) | catalogued as rs1469639646; called by muse, mutect2, varscan2
- CXXC1 | c.1041G>C p.R347= | Silent (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2, varscan2
- DLG3 | c.240G>T p.R80= | Silent (SNP) | VAF 238/651 reads (37%) | called by muse, mutect2, varscan2
- DMD | c.60A>G p.T20= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs771449240; called by muse, varscan2
- ENKUR | c.21T>A p.S7= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs757460349; called by muse, mutect2, varscan2
- FRMD7 | c.1401G>A p.V467= | Silent (SNP) | VAF 105/302 reads (35%) | called by muse, mutect2, varscan2
- KLK5 | c.237G>A p.P79= | Silent (SNP) | VAF 20/363 reads (6%) | catalogued as COSV100306753; called by muse, mutect2
- LAMB1 | c.4317C>T p.N1439= | Silent (SNP) | VAF 284/518 reads (55%) | catalogued as rs143816350; called by muse, mutect2, varscan2
- PCDH19 | c.1536A>C p.S512= | Silent (SNP) | VAF 18/626 reads (3%) | called by muse, mutect2
- PHACTR4 | c.786C>A p.P262= (on ENST00000373839 / NM_001350159.2; = p.P272= on NM_023923.4) | Silent (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- SPATA2L | c.522C>G p.T174= | Silent (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- TENM3 | c.3582G>A p.V1194= | Silent (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- TG | c.6882T>G p.P2294= | Silent (SNP) | VAF 123/792 reads (16%) | called by muse, mutect2, varscan2
- TMEM119 | c.180G>A p.P60= | Silent (SNP) | VAF 119/292 reads (41%) | catalogued as rs758127769; called by muse, mutect2, varscan2
- VGLL4 | c.489C>G p.S163= | Silent (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- ZNF835 | c.541C>T p.L181= | Silent (SNP) | VAF 126/213 reads (59%) | catalogued as rs1007277746; called by muse, mutect2, varscan2
- ALB | c.844-33C>G | Intron (SNP) | VAF 66/109 reads (61%) | called by muse, mutect2, varscan2
- CBWD3 | c.528+829C>T | Intron (SNP) | VAF 20/80 reads (25%) | catalogued as rs781926096, COSV64132257; called by muse, mutect2, varscan2
- EPB41L4A | chr5:112420332 G>A | 5'Flank (SNP) | VAF 65/150 reads (43%) | called by muse, mutect2, varscan2
- MROH7 | c.2965-178T>C | Intron (SNP) | VAF 99/407 reads (24%) | called by muse, mutect2, varscan2
- MRPL3 | c.-28C>T | 5'UTR (SNP) | VAF 62/151 reads (41%) | catalogued as rs1207942033; called by muse, mutect2, varscan2
- TM6SF2 | c.297+32C>T | Intron (SNP) | VAF 188/494 reads (38%) | catalogued as rs370326434, COSV101231579; called by mutect2, varscan2
- TMEM59L | c.664+107C>T | Intron (SNP) | VAF 91/765 reads (12%) | called by muse, mutect2, varscan2
